MMRF case MMRF_2016 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0f00e9ca-b8ab-468f-a5f5-087e6b3718ee

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 76.4 years (27,888 days); ISS stage: III; Days to last known disease status: 978 days (2.7 years); Days to last follow up: 978 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Lenalidomide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 3): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.434 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Immunoglobulin G 69.3 g/L; Immunoglobulin A 0.0887 g/L; Immunoglobulin M 0.124 g/L; Beta 2 Microglobulin 8.82 µg/mL; Lactate Dehydrogenase 1.5 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 2.96 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.4 mmol/L; Albumin 29.5 g/L; Total Protein 10.1 g/dL; Glucose 5.1 mmol/L; C-Reactive Protein 0.98 mg/dL.
- Day 71 (ECOG 2): M Protein 1.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.585 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.172 g/L; Immunoglobulin M 0.226 g/L; Beta 2 Microglobulin 2.77 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.95 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 72 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.44 mmol/L; Albumin 38.9 g/L; Total Protein 7.4 g/dL; Glucose 5.2 mmol/L.
- Day 180 (ECOG 2): M Protein 6.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.473 g/L; Immunoglobulin M 0.274 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 3.79 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 74 µmol/L; Blood Urea Nitrogen 5.31 mmol/L; Calcium 2.39 mmol/L; Albumin 38.4 g/L; Total Protein 6.64 g/dL; Glucose 5.5 mmol/L.
- Day 250 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.846 g/L; Immunoglobulin M 0.393 g/L; Beta 2 Microglobulin 2.54 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 80 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 6.31 g/dL; Glucose 6 mmol/L.
- Day 341 (ECOG 1): M Protein 0 g/dL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 3.28 ×10⁹/L; Absolute Neutrophil 1.14 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 86 µmol/L; Blood Urea Nitrogen 5.11 mmol/L; Calcium 2.45 mmol/L; Albumin 39.3 g/L; Total Protein 6.29 g/dL; Glucose 5.6 mmol/L.
- Day 442 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 9.32 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.88 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 3.31 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 95 µmol/L; Blood Urea Nitrogen 7.2 mmol/L; Calcium 2.35 mmol/L; Albumin 38.1 g/L; Total Protein 6.26 g/dL; Glucose 6.4 mmol/L.
- Day 530 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 8.33 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.203 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.66 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.6 mmol/L.
- Day 614 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.96 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 92 µmol/L; Blood Urea Nitrogen 7 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.6 mmol/L.
- Day 719 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.323 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 79 µmol/L; Calcium 2.3 mmol/L; Albumin 39.4 g/L; Total Protein 6.25 g/dL; Glucose 5.6 mmol/L.
- Day 894 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.193 g/L; Beta 2 Microglobulin 2.81 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.7 mmol/L.
- Day 978 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 1.26 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.06 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 83 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.3 mmol/L; Albumin 37.9 g/L; Total Protein 5.9 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -7: Weight: 84 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2016_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2016_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
